Surgical pathology report (de-identified scan), TCGA case TCGA-DU-5870, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-5870-02A (Recurrent Tumor).

[page 1 of 2]
Anatomic Pathology/Cytology Document State: (version)
Update Date/Time:
Final 1

Patient Name: MRN:
DOB/Age/Gender: Female Provider:
Location: Responsible Staff:

Service Date/Time:

Recurrence

EC0-3

Oligodendroglioma, grade III
Site ^{CCF} Brain, supratentorial NOS
9451/3
271.0
Brain, temporal lobe
949/30/13 271.2

Surgical Pathology Report

Patient Name:

Med: Rec.:

DOB:

Gender: F

Client:

Taken:

Received:

Reported:

Physician(s):

Phy Location:

Accession #:
Phone Number:

CLINICAL HISTORY

-year-old woman had a right temporal oligodendroglioma removed
, a recurrence diagnosed on and currently has a
focal area of enhancement.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, right temporal, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. Brain, right temporal, excisional biopsies: Oligodendroglioma,
anaplastic. MIB-1 proliferation index: 10%.

See Comment.

COMMENT

The specimen is fragments of cerebrum heavily infiltrated and focally effaced by an oligodendroglial neoplastic proliferation. The neoplastic nuclei have moderate anaplasia, and there are some mitotic figures. There are also frequent gemistocytes, mostly mini gemistocytes. There is no appreciable microvascular cellular proliferation or necrosis. The MIB-1 proliferation index is about 10% throughout the tumor. These features indicate the neoplasm has undergone anaplastic transformation.

Electronically Signed Out

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered:

Date Reported:

Interpretation

POSITIVE - Methylated MGMT promoter is detected.

Results-Comments

Testing was done on block

(A2).

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the

as

[page 2 of 2]
required by CLIA ' 88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.
Electronically Signed Out

Consultant:

=====

INTRA-OPERATIVE CONSULTATION

A.

Brain, touch prep and smears: Glioma, C/W oligodendroglioma, atypical.
Frozen section performed at _____ and results reported to the
Physician of Record.

GROSS DESCRIPTION

A.

Received fresh, several fragments, 1.6 cm. in aggregate. Soft and semi firm, tannish-purple. In total, A1-A3.

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates many gemistocytes (mini- and classical). About 5% of neoplastic cells over express the p53 protein. With the MIB-1, there is a proliferation index of about 10% throughout the tumor.

ICD-9(s):

191.2 191.2

Billing Fee Code(s):

A:

MGMT:

Histo Data

Part A: Brain, right temporal, excision biopsy

Taken: _____ Received:

Stain/cnt Block Ordered Comment

H/E x 1 1

CD31-DA x 1 2

mGFAP-DA x 1 2

H/E x 1 2

MGMT x 1 2

MIB1-DA x 1 2

P53DO7 x 1 2

H/E x 1 3

*** End of Report ***

H2A Discrepancy		✓
Print Malignancy History		✓

Source: NCI Genomic Data Commons file 12486624-e485-4938-9f5e-8b878ce852cb (TCGA-DU-5870.5A7D5219-AFF1-4DC0-9A8B-F6403D021501.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).